Gene-level copy-number profile of tumor specimen TCGA-BA-4076-01A from TCGA case TCGA-BA-4076, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 39.4 years (14,405 days).
Specimen TCGA-BA-4076-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.fb43b6dc-1336-4365-b852-969887186019.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-4076-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e98556c2-59c5-4652-b340-f9a25e931b7c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 14,876; copy number 2: 37,570; copy number 3: 4,361; copy number 4: 2,024; copy number 5: 159; copy number 6: 182; copy number 7: 63; copy number 8: 182; copy number 9: 181; copy number 10: 56; copy number 11: 31; copy number 13: 22; copy number 15: 88.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-4076-01A-01D-1432-01): tumor purity 0.85, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,929,457–22,128,103, 9 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 964 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:132,085,084–140,205,326, 165 genes, copy number 5–13 (broad region; genes not listed).
- chr6:141,403,240–147,204,614, 78 genes, copy number 5–11 (within-gene range 1–11) (broad region; genes not listed).
- chr7:53,490,148–57,074,664, 105 genes, copy number 9 (broad region; genes not listed).
- chr7:100,620,416–101,018,949, 21 genes, copy number 5 (within-gene range 1–5): TFR2, ACTL6B, GNB2, GIGYF1, POP7, EPO, ZAN, EPHB4, RN7SL750P, SLC12A9, SLC12A9-AS1, TRIP6, MIR6875, SRRT, UFSP1, ACHE, RN7SL549P, RPS29P15, MUC3A, AC254629.1, MUC12.
- chr11:68,891,276–70,436,584, 50 genes, copy number 15: MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 15: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr14:32,149,176–36,679,362, 89 genes, copy number 6 (broad region; genes not listed).
- chr14:59,135,488–68,730,218, 182 genes, copy number 8 (within-gene range 1–8) (broad region; genes not listed).
- chr14:71,212,633–73,123,899, 27 genes, copy number 5 (within-gene range 4–5): AC004817.1, AC004817.4, AC005476.2, SIPA1L1, AC005476.1, SNORD56B, RN7SL683P, AC004974.1, AC004900.1, AC005993.1, RGS6, Y_RNA, AC004828.2, MIR7843, AC004828.1, DPF3, AL392024.1, Y_RNA, DCAF4, AC007160.1, AL442663.4, AL442663.1, ZFYVE1, RN7SL586P, AL442663.3, RBM25, AL442663.2.
- chr16:61,638,233–65,646,947, 34 genes, copy number 5: AC092125.2, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1, AC009110.1, AC010546.1, AC040174.1, AC040174.2, UBE2FP2, AC138305.1, RPS15AP34, AC138305.2, AC138305.3, AC018846.1, LINC02165, AC092337.1, AC093536.2, AC012322.1, AC093536.1, AC092131.1, PPIAP48, AC009101.1, CDH11, AC010533.1, LINC02126, AC009055.2, AC009055.1, LINC00922, AC092138.2, AC092138.1.
- chr18:2,655,726–5,385,330, 56 genes, copy number 10–15 (within-gene range 1–15): SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1, PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1.
- chr18:5,463,627–5,480,975, 1 gene, copy number 10 (within-gene range 4–10): AP005059.2.
- chr18:22,586,465–26,657,401, 76 genes, copy number 6 (broad region; genes not listed).
- chr18:26,685,954–26,865,771, 6 genes, copy number 6: AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4.
- chr18:35,366,694–42,691,422, 68 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,490. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
